Somatic mutation profile of tumor specimen TCGA-78-7535-01A (aliquot TCGA-78-7535-01A-11D-2063-08) from TCGA case TCGA-78-7535, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 45.4 years (16,571 days).
Specimen TCGA-78-7535-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65b73b0e-67a7-43b6-8719-8935176d13f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7535-10A (Blood Derived Normal), aliquot TCGA-78-7535-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84a48edd-9391-4b35-b78c-506fd1191abc

The open-access MAF lists 188 somatic variants for this specimen: 130 protein-altering or splice-affecting, 54 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 54, Frame Shift Del 3, Nonsense Mutation 3, RNA 3, Splice Site 2, Splice Region 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, varscan2
- ADAMTS16 | c.1313+2T>G p.X438_splice | Splice Site (SNP) | VAF 49/132 reads (37%) | catalogued as COSV56997435; called by muse, mutect2, varscan2
- ADARB1 | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV62345844; called by muse, mutect2, varscan2
- AFF3 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57861807; called by muse, mutect2, varscan2
- AMER3 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58468212; called by muse, mutect2, varscan2
- ANO2 | c.2543T>A p.L848H (on ENST00000356134 / NM_001278597.3; = p.L852H on NM_001278596.3) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59032612; called by muse, mutect2, varscan2
- ASTN1 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1344289242, COSV62500635; called by muse, mutect2, varscan2
- ATG2B | c.2287T>C p.S763P | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV63424288; called by muse, mutect2, varscan2
- ATP1A4 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV63627304; called by muse, mutect2, varscan2
- ATP1B4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV54311354; called by muse, mutect2, varscan2
- BRINP2 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1158343415; called by muse, mutect2, varscan2
- C19orf54 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.52); catalogued as COSV54576018; called by muse, mutect2, varscan2
- CAMK1G | c.682T>C p.F228L | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV50523928; called by muse, mutect2, varscan2
- CAMK4 | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as COSV56676692; called by muse, mutect2, varscan2
- CCDC178 | c.2415C>A p.H805Q (on ENST00000383096 / NM_001105528.3; = p.H767Q on NM_198995.3) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV55783833; called by muse, mutect2, varscan2
- CCDC88A | c.4894C>A p.H1632N (on ENST00000436346 / NM_001365480.1; = p.H1604N on NM_018084.5) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55065538; called by muse, mutect2, varscan2
- CDH10 | c.990C>G p.I330M | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV52573076, COSV52587964; called by muse, mutect2, varscan2
- CFC1 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV52090677; called by muse, mutect2, varscan2
- COL6A2 | c.890C>G p.P297R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56010521; called by muse, mutect2
- CPA4 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs766899795, COSV55984125; called by muse, mutect2, varscan2
- CSMD3 | c.4192G>T p.G1398W (on ENST00000297405 / NM_001363185.1; = p.G1294W on NM_052900.3) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52241135; called by muse, mutect2, varscan2
- CTTNBP2 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.328); catalogued as COSV50421878; called by muse, mutect2, varscan2
- CYP11B2 | c.1129C>G p.P377A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV59996827; called by muse, mutect2, varscan2
- CYRIA | c.855A>C p.K285N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62864409, COSV62865839, COSV62867483; called by muse, mutect2, varscan2
- DAB1 | c.1201C>A p.P401T (on ENST00000371231; = p.P368T on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs754773594, COSV64695094; called by muse, mutect2, varscan2
- DAB2 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV57916446; called by muse, mutect2, varscan2
- DAB2 | c.1028T>C p.F343S | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57916458; called by muse, mutect2
- DLD | c.239G>T p.C80F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52738805; called by muse, mutect2, varscan2
- DPP6 | c.1114C>A p.P372T (on ENST00000377770 / NM_001364500.2; = p.P310T on NM_001936.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV59628724; called by muse, mutect2, varscan2
- DPP8 | c.832G>C p.D278H (on ENST00000341861 / NM_001320875.2; = p.D262H on NM_017743.6) | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1484831836, COSV55680769; called by muse, mutect2, varscan2
- DYSF | c.5268G>T p.Q1756H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV50473800; called by muse, mutect2, varscan2
- EDIL3 | c.1191A>C p.K397N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56908164; called by muse, mutect2, varscan2
- EFCAB6 | c.4201C>G p.H1401D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV53067235; called by muse, mutect2, varscan2
- EIF2AK1 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs998344120, COSV52241067; called by muse, mutect2, varscan2
- ENPP1 | c.1233C>A p.N411K | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV62934104; called by muse, mutect2, varscan2
- FAM171B | c.2136T>A p.N712K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59005771; called by muse, mutect2, varscan2
- FAM50B | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66654724, COSV66654948; called by muse, mutect2, varscan2
- FCGR3B | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.795); catalogued as COSV54209355; called by muse, mutect2
- FLG2 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as COSV66170551; called by muse, mutect2, varscan2
- FLNA | c.1637T>C p.V546A | Missense Mutation (SNP) | VAF 70/96 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV61047089; called by muse, mutect2, varscan2
- FRMPD1 | c.2344G>T p.G782C | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV66701248; called by muse, mutect2, varscan2
- FRYL | c.4415A>G p.K1472R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51953364; called by muse, mutect2, varscan2
- GFRA2 | c.613C>A p.R205S | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV60780249; called by muse, mutect2, varscan2
- GTF3C3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.034); catalogued as COSV55833225; called by muse, mutect2, varscan2
- HAUS8 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53726718; called by muse, mutect2, varscan2
- HCN1 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57523041; called by muse, mutect2, varscan2
- HEATR1 | c.5629T>G p.F1877V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV63982083; called by muse, mutect2
- HNRNPLL | c.732A>T p.P244= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as rs771501973, COSV55368358; called by muse, mutect2, varscan2
- HOXD12 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101184334; called by muse, mutect2, varscan2
- IFT88 | c.1294G>C p.V432L (on ENST00000319980 / NM_001318493.2; = p.V423L on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV60675105; called by muse, mutect2, varscan2
- IL18RAP | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs1402319386, COSV51827427; called by muse, mutect2, varscan2
- ILDR2 | c.1259C>A p.T420K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV54833051; called by muse, mutect2, varscan2
- ITPRIPL1 | c.991G>C p.A331P (on ENST00000439118 / NM_001008949.3; = p.A339P on NM_178495.6) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.373); catalogued as COSV63154054; called by muse, mutect2, varscan2
- KIRREL3 | c.1408G>T p.V470L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV69385376; called by muse, mutect2, varscan2
- KIRREL3 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs746537426, COSV73106318; called by muse, mutect2, varscan2
- KLF4 | c.1318T>G p.S440A | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65929256; called by muse, mutect2, varscan2
- KRTAP19-5 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.033); catalogued as COSV61859202; called by muse, mutect2, varscan2
- LAMA1 | c.4339A>T p.S1447C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV67539998; called by muse, mutect2, varscan2
- LAMA3 | c.6020G>A p.R2007K (on ENST00000313654 / NM_198129.4; = p.R398K on NM_000227.6) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52538299; called by muse, mutect2, varscan2
- LCE2A | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV64227005; called by muse, mutect2, varscan2
- LIG4 | c.446A>T p.N149I | Missense Mutation (SNP) | VAF 114/166 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597509; called by muse, mutect2
- LONP2 | c.868T>C p.C290R | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV53524009; called by muse, mutect2, varscan2
- LRPAP1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56347049; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1520T>G p.L507R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53798252, COSV53798931; called by muse, mutect2
- MINAR1 | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV59584535; called by muse, mutect2, varscan2
- MUC16 | c.6362T>G p.L2121W | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV67478780; called by muse, mutect2, varscan2
- MYH2 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55442513, COSV99819733; called by muse, mutect2, varscan2
- NBEA | c.4601C>A p.P1534Q | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.579); catalogued as COSV59777063, COSV59801297; called by muse, mutect2, varscan2
- NDST4 | c.2123G>T p.R708L | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs764667030, COSV52110213, COSV52127649; called by muse, mutect2, varscan2
- NETO1 | c.927G>C p.L309F | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55004865, COSV55010262; called by muse, mutect2, varscan2
- NFAT5 | c.2572G>C p.D858H | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV63029740; called by muse, mutect2, varscan2
- NIBAN2 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64824870; called by muse, mutect2, varscan2
- NOBOX | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV56195848; called by muse, mutect2, varscan2
- NUF2 | c.935G>T p.S312I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54845047; called by muse, mutect2, varscan2
- OR11H6 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 82/143 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59644608; called by muse, mutect2, varscan2
- OR2M7 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 153/414 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.379); catalogued as COSV100522714; called by muse, mutect2, varscan2
- OR4E2 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 146/270 reads (54%) | catalogued as COSV57732009; called by muse, mutect2, varscan2
- OR51D1 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs759656555, COSV62914428; called by muse, mutect2, varscan2
- OR52N2 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1296345194, COSV57677275; called by muse, mutect2, varscan2
- OR6N2 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs1302431130, COSV59412135; called by muse, mutect2, varscan2
- OR8H1 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 92/315 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV57296427; called by muse, mutect2, varscan2
- OR9A4 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV71885726; called by muse, mutect2, varscan2
- PABPC5 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs779133384, COSV57039569, COSV57042673; called by muse, mutect2, varscan2
- PANK3 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV53324115, COSV53324478; called by muse, mutect2, varscan2
- PAPPA2 | c.4006C>T p.H1336Y | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62803742; called by muse, mutect2, varscan2
- PAX8 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV54508759, COSV54510517; called by muse, mutect2, varscan2
- PCDHB11 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV53381324; called by muse, mutect2, varscan2
- PDZD8 | c.1057A>C p.S353R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57826902; called by muse, mutect2, varscan2
- PGBD5 | c.747G>T p.K249N (on ENST00000525115; = p.K318N on NM_001258311.2) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58412588; called by muse, mutect2, varscan2
- PREX1 | c.3182A>T p.D1061V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV64254002; called by muse, mutect2, varscan2
- PRLR | c.1056del p.S353Afs*45 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as COSV99184418; called by mutect2, pindel, varscan2
- PSG3 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs1400897373, COSV59503154, COSV59505568; called by muse, mutect2, varscan2
- RAD54L | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV64336529; called by muse, mutect2, varscan2
- RANBP17 | c.2463G>T p.Q821H | Missense Mutation (SNP) | VAF 81/149 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV66653422, COSV66654835; called by muse, mutect2, varscan2
- SATB2 | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559136030, COSV53483172, COSV53488467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA9 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV54076405; called by muse, mutect2, varscan2
- SFMBT2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.798); catalogued as rs780266353, COSV62812732; called by muse, mutect2, varscan2
- SLC25A44 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63962007; called by muse, mutect2, varscan2
- SLC26A7 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771372610, COSV52598347, COSV99402146; called by muse, mutect2, varscan2
- SLC34A1 | c.1879C>A p.R627S | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV53692126; called by muse, mutect2, varscan2
- SLFN11 | c.2128T>G p.L710V | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.176); catalogued as COSV100390963, COSV57699636; called by muse, mutect2, varscan2
- SMG5 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.439); catalogued as COSV62436433; called by muse, mutect2, varscan2
- SNAI2 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV50079654; called by muse, mutect2, varscan2
- SSTR5 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV53511350, COSV53512764; called by muse, mutect2
- STAT4 | c.511T>A p.F171I | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61831019; called by muse, mutect2, varscan2
- STC2 | c.28A>G p.M10V | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54180958; called by muse, mutect2, varscan2
- STYXL2 | c.3396G>T p.M1132I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV54807440; called by muse, mutect2, varscan2
- TAS1R2 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs370587266; called by muse, mutect2
- TAS2R5 | c.94T>A p.F32I | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.11); catalogued as COSV56095231; called by muse, mutect2, varscan2
- TENT4A | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1289998665, COSV50097101; called by muse, mutect2, varscan2
- TMPRSS13 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as rs1044111689, COSV70626868; called by muse, mutect2, varscan2
- TNP1 | c.104A>T p.K35M | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV52696856; called by muse, mutect2, varscan2
- TNR | c.1568A>T p.E523V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54898950; called by muse, mutect2, varscan2
- TNR | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54898964, COSV99686717; called by muse, mutect2, varscan2
- TONSL | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68048819; called by muse, mutect2, varscan2
- TRIM22 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV66091224; called by muse, mutect2, varscan2
- TRIM51 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV55268643; called by muse, mutect2
- TRPC6 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.011); catalogued as COSV60257738; called by muse, mutect2, varscan2
- TRPS1 | c.2579G>T p.G860V (on ENST00000220888 / NM_001330599.2; = p.G873V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV55250809; called by muse, mutect2, varscan2
- UBE2U | c.67-2A>G p.X23_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | catalogued as COSV64281260; called by muse, mutect2, varscan2
- XG | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV66985890; called by muse, mutect2, varscan2
- ZBTB41 | c.2074G>C p.G692R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66359468; called by muse, mutect2, varscan2
- ZFHX4 | c.2740T>A p.S914T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1397217393, COSV50774433, COSV51470847; called by muse, mutect2, varscan2
- ZNF804B | c.1844A>T p.K615M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV60838939; called by muse, mutect2, varscan2
- HOXD12 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KIAA1522 | c.2183del p.F728Sfs*88 (on ENST00000373480 / NM_001198972.2; = p.F787Sfs*88 on NM_020888.3) | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- NF1 | c.403_406del p.R135Ifs*29 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | called by mutect2, pindel, varscan2
- OR14K1 | c.498T>G p.F166L | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- RAI1 | c.692dup p.A233Gfs*5 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- VCX3A | c.324C>G p.S108R | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, varscan2
- ACTRT2 | c.996G>T p.T332= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as COSV65759040, COSV65759805; called by muse, mutect2, varscan2
- ALPK2 | c.4671G>A p.T1557= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as rs561304855, COSV100864957, COSV64491330; called by muse, mutect2, varscan2
- ASTN2 | c.3942C>A p.L1314= (on ENST00000313400 / NM_001365069.1; = p.L1263= on NM_014010.5) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV56009343; called by muse, mutect2, varscan2
- ATG9A | c.1716G>A p.E572= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV54697978; called by muse, mutect2, varscan2
- BRINP2 | c.591G>C p.L197= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- CARF | c.1656C>T p.S552= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV57548679; called by muse, mutect2, varscan2
- CCKAR | c.891G>T p.R297= | Silent (SNP) | VAF 58/170 reads (34%) | catalogued as COSV55159586, COSV55162510; called by muse, mutect2, varscan2
- CHST3 | c.249C>A p.L83= | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as COSV64151309; called by muse, mutect2, varscan2
- COL4A5 | c.4464T>A p.S1488= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as COSV60366022; called by muse, mutect2, varscan2
- DNAH7 | c.5475T>C p.D1825= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV56774172; called by muse, mutect2, varscan2
- DOLK | c.1254C>T p.P418= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV58281460; called by muse, mutect2, varscan2
- FAM47C | c.867T>C p.T289= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV63728451; called by muse, mutect2
- GFUS | c.618G>T p.T206= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV55307802; called by muse, mutect2, varscan2
- GIMAP1 | c.351G>A p.L117= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV56188995, COSV56189937; called by muse, mutect2, varscan2
- GLI2 | c.765G>T p.S255= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs200901345, COSV58040532, COSV58046160; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1239G>A p.L413= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1554348320, COSV56088861; called by muse, mutect2, varscan2
- HOXA10 | c.75C>A p.A25= | Silent (SNP) | VAF 58/113 reads (51%) | catalogued as COSV52230053; called by muse, mutect2, varscan2
- ITIH5 | c.2223G>A p.L741= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV53669784; called by muse, mutect2, varscan2
- JPH2 | c.1125C>A p.R375= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV65903554, COSV65904542; called by muse, mutect2, varscan2
- JPH3 | c.798G>T p.L266= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV52470403; called by muse, mutect2
- KCNE1 | c.300G>T p.L100= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV61607085, COSV61607371; called by mutect2, varscan2
- KCNH6 | c.729C>T p.R243= | Silent (SNP) | VAF 65/116 reads (56%) | catalogued as COSV59005297; called by muse, mutect2, varscan2
- KIF3C | c.195T>C p.D65= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV53100645; called by muse, mutect2, varscan2
- LIG4 | c.444A>T p.V148= | Silent (SNP) | VAF 114/170 reads (67%) | catalogued as COSV63597515; called by muse, mutect2
- MMP9 | c.1026G>T p.S342= | Silent (SNP) | VAF 54/172 reads (31%) | catalogued as COSV63434249; called by muse, mutect2, varscan2
- MOGAT3 | c.882C>A p.P294= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV56175498; called by muse, mutect2, varscan2
- MUC17 | c.6774T>G p.T2258= | Silent (SNP) | VAF 87/600 reads (15%) | catalogued as COSV60295314; called by muse, mutect2, varscan2
- MYH11 | c.4563T>C p.D1521= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV55560631; called by muse, mutect2, varscan2
- MYO7B | c.297C>T p.G99= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1367819026, COSV67349316; called by muse, mutect2
- NRCAM | c.3252C>T p.I1084= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100694535, COSV61042192; called by muse, mutect2, varscan2
- OPTN | c.525A>G p.E175= | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as rs753825586, COSV53811906; called by muse, mutect2, varscan2
- OR1N1 | c.819T>A p.A273= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV59196109; called by muse, mutect2, varscan2
- OR2A12 | c.288C>T p.C96= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV68821729; called by muse, mutect2, varscan2
- OR2M2 | c.525C>A p.A175= | Silent (SNP) | VAF 211/554 reads (38%) | catalogued as COSV100677190, COSV62898846; called by muse, mutect2, varscan2
- OR2M7 | c.348T>C p.A116= | Silent (SNP) | VAF 151/411 reads (37%) | called by muse, mutect2, varscan2
- OR2T12 | c.366G>T p.A122= | Silent (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- OR8D2 | c.369T>C p.Y123= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV62488710; called by muse, mutect2, varscan2
- OR8H1 | c.129G>T p.V43= | Silent (SNP) | VAF 90/309 reads (29%) | called by muse, mutect2, varscan2
- PCDHB7 | c.84C>A p.A28= | Silent (SNP) | VAF 51/89 reads (57%) | catalogued as COSV50790853, COSV99176887; called by muse, mutect2, varscan2
- PGR | c.2253T>A p.I751= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV54805568; called by muse, mutect2, varscan2
- PITHD1 | c.480C>T p.F160= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs770250248, COSV55754552; called by muse, mutect2, varscan2
- PKD1 | c.4029G>T p.P1343= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV51920387; called by muse, mutect2, varscan2
- PSG3 | c.1122A>C p.L374= | Silent (SNP) | VAF 160/303 reads (53%) | catalogued as COSV59505557; called by muse, mutect2, varscan2
- PTGES3 | c.471A>T p.P157= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV56274231; called by muse, mutect2, varscan2
- REPIN1 | c.744G>A p.K248= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs747511625, COSV68292647; called by muse, mutect2, varscan2
- SCRT1 | c.888G>A p.Q296= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV59781755; called by muse, mutect2, varscan2
- SLIT2 | c.3036A>T p.T1012= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV56582316; called by muse, mutect2, varscan2
- TPST1 | c.328C>T p.L110= | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- TRIM51 | c.1173C>A p.L391= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as COSV55268660; called by muse, varscan2
- TSHR | c.1488G>A p.T496= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as rs779531801, COSV53325659; called by muse, mutect2, varscan2
- TSPAN11 | c.723C>A p.T241= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV53819818; called by muse, mutect2, varscan2
- WNT4 | c.126G>C p.T42= | Silent (SNP) | VAF 74/234 reads (32%) | catalogued as COSV51604658; called by muse, mutect2, varscan2
- XIRP2 | c.7218A>G p.T2406= (on ENST00000628543; = p.T2581= on NM_152381.6) | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV54715897; called by muse, mutect2, varscan2
- ZC3H12C | c.2056A>C p.R686= | Silent (SNP) | VAF 68/341 reads (20%) | catalogued as COSV53710538; called by muse, mutect2, varscan2
- DDHD1 | chr14:53152752 G>A | 5'Flank (SNP) | VAF 9/11 reads (82%) | catalogued as rs1246089061, COSV60360629; called by muse, mutect2, varscan2
- MIR379 | n.22G>T | RNA (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- MIR411 | n.34A>T | RNA (SNP) | VAF 32/46 reads (70%) | called by muse, mutect2, varscan2
- SERPINA13P | n.692C>G | RNA (SNP) | VAF 62/97 reads (64%) | called by muse, mutect2, varscan2
